Somatic mutation profile of tumor specimen TCGA-93-A4JN-01A (aliquot TCGA-93-A4JN-01A-11D-A24P-08) from TCGA case TCGA-93-A4JN, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 71.9 years (26,273 days).
Specimen TCGA-93-A4JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 413940e1-c35b-41ca-a381-381deff762f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-A4JN-10A (Blood Derived Normal), aliquot TCGA-93-A4JN-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/590f514e-a6a5-4a9c-a653-5709525281ea

The open-access MAF lists 75 somatic variants for this specimen: 60 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 50, Silent 15, Nonsense Mutation 7, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABL1 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs774185202, COSV100583622; called by muse, mutect2, varscan2
- ANKRD17 | c.4117G>A p.V1373M | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100428767; called by muse, mutect2, varscan2
- APOA4 | c.880G>T p.G294W | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100759275, COSV100759364, COSV63360504; called by muse, mutect2, varscan2
- ASB2 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.567); catalogued as COSV100279264; called by muse, mutect2
- ASTN2 | c.1126A>T p.S376C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV100525553; called by muse, varscan2
- ATM | c.7263A>C p.K2421N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as COSV99588182; called by muse, mutect2, varscan2
- BIRC6 | c.3320A>G p.K1107R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV101428000; called by muse, mutect2, varscan2
- BRSK1 | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.987); catalogued as COSV58664461; called by muse, mutect2, varscan2
- CAND2 | c.967G>C p.E323Q (on ENST00000456430 / NM_001162499.2; = p.E230Q on NM_012298.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as rs761315087, COSV99928794, COSV99929640; called by muse, mutect2, varscan2
- CHGA | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV50895418, COSV99381017; called by muse, mutect2, varscan2
- CPXM2 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53872365, COSV99581396; called by muse, mutect2, varscan2
- DDX39B | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 23/116 reads (20%) | catalogued as COSV100795180; called by muse, mutect2, varscan2
- DOK2 | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as COSV99374622; called by muse, mutect2, varscan2
- EHBP1 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99860369; called by muse, mutect2, varscan2
- ELAVL2 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.096); catalogued as rs1358307500, COSV99805688; called by muse, mutect2
- F7 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as rs977631643, COSV100660970; called by muse, varscan2
- FAM47A | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100650092, COSV60494022; called by muse, mutect2, varscan2
- FBN2 | c.4286C>T p.P1429L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as rs771467729, COSV99325827, COSV99331136; called by muse, mutect2, varscan2
- FLCN | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99550207; called by muse, mutect2, varscan2
- LAMA1 | c.607A>G p.N203D | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055552; called by muse, varscan2
- LRRC36 | c.1659C>T p.L553= | Splice Region (SNP) | VAF 49/166 reads (30%) | catalogued as rs988545000, COSV99338502; called by muse, mutect2, varscan2
- MAGEB6 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100983689; called by muse, mutect2, varscan2
- MARK1 | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as rs901442620, COSV100857114; called by muse, mutect2, varscan2
- MRGPRX3 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as rs770342530, COSV66933999; called by muse, mutect2, varscan2
- MRPS14 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100871526; called by muse, mutect2
- MTUS1 | c.2372G>A p.S791N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100029207; called by muse, mutect2
- MYO9A | c.1099A>T p.I367L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV100612926; called by muse, mutect2, varscan2
- MYT1L | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV101219484; called by muse, mutect2
- NKAP | c.738G>C p.S246= | Splice Region (SNP) | VAF 19/60 reads (32%) | catalogued as COSV101004200; called by muse, mutect2
- OGN | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99364016; called by muse, mutect2
- OLR1 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV100376325; called by muse, mutect2, varscan2
- OR13F1 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100594712; called by muse, mutect2
- OR4Q3 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100056850; called by muse, mutect2, varscan2
- OR56A1 | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100360415; called by muse, mutect2, varscan2
- PCDHA9 | c.1054A>C p.I352L | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100969229; called by muse, mutect2
- PHACTR3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs145693547; called by muse, mutect2, varscan2
- PKD2 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV99417055; called by muse, mutect2, varscan2
- PRDM8 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100325021; called by muse, varscan2
- PSG6 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 22/370 reads (6%) | catalogued as rs1043165999, COSV51830662, COSV99413742; called by muse, mutect2
- PTGER2 | c.280G>C p.A94P | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV99817363; called by muse, mutect2, varscan2
- RB1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as CD941772, CM0910366, COSV57296743, COSV57307114; called by muse, mutect2, varscan2
- RP1 | c.6332T>C p.V2111A | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as rs1226021517, COSV99606706; called by muse, mutect2, varscan2
- RPS6KA6 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99424357; called by muse, mutect2
- RYR1 | c.5171G>A p.R1724H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs372800648; called by muse, mutect2, varscan2
- RYR3 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.116); catalogued as rs1294013048, COSV101212215; called by muse, mutect2, varscan2
- SATB2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs1399958038, COSV53482313; called by muse, mutect2
- SERPINA11 | c.567C>A p.Y189* | Nonsense Mutation (SNP) | VAF 47/159 reads (30%) | catalogued as rs146841701, COSV100593970; called by muse, mutect2, varscan2
- SLITRK5 | c.1499C>T p.T500I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100280501; called by muse, mutect2, varscan2
- SSH2 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99281641; called by muse, mutect2, varscan2
- TATDN3 | c.778A>G p.N260D | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100875203; called by muse, mutect2
- TNR | c.3337C>G p.Q1113E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.42); catalogued as COSV99688366; called by muse, mutect2, varscan2
- UNC5D | c.2795T>C p.L932P | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as COSV99773323; called by muse, mutect2, varscan2
- USH2A | c.5479G>A p.G1827R | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs745762091, COSV56385811, COSV56419974; called by muse, mutect2, varscan2
- ZNF354B | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs763648278, COSV100482924; called by muse, mutect2, varscan2
- ZNF398 | c.1340G>A p.R447K (on ENST00000475153 / NM_170686.3; = p.R276K on NM_020781.4) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV100246852; called by muse, mutect2, varscan2
- ZNF507 | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100321648; called by muse, mutect2, varscan2
- ZNF777 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99925050; called by muse, mutect2, varscan2
- ZNF782 | c.1661G>C p.R554T | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100001260, COSV56654860; called by muse, mutect2, varscan2
- YLPM1 | c.2023del p.V675Cfs*24 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- ASB2 | c.654C>A p.S218= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as rs551558470, COSV100279263; called by muse, mutect2
- ASXL3 | c.4077G>A p.L1359= | Silent (SNP) | VAF 20/221 reads (9%) | catalogued as COSV52474863; called by muse, mutect2
- ATP9A | c.1963C>T p.L655= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1191299367, COSV100124513; called by muse, mutect2, varscan2
- FAM181A | c.516T>A p.A172= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99967833; called by muse, mutect2, varscan2
- ITFG1 | c.585G>A p.L195= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100278481; called by muse, mutect2, varscan2
- KCNK9 | c.1020C>T p.S340= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100270564, COSV57277793; called by muse, mutect2, varscan2
- OR52A5 | c.189T>A p.I63= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100263332; called by muse, mutect2, varscan2
- OR8B12 | c.243G>A p.L81= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV100172686; called by muse, mutect2
- PTPN23 | c.472C>A p.R158= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99650342; called by muse, mutect2, varscan2
- RAB3D | c.219G>C p.L73= | Silent (SNP) | VAF 32/273 reads (12%) | catalogued as COSV99708766; called by muse, mutect2, varscan2
- TAF1L | c.135C>T p.I45= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99644311; called by muse, mutect2, varscan2
- TOX2 | c.1005C>A p.A335= (on ENST00000358131 / NM_001098798.2; = p.A311= on NM_032883.3) | Silent (SNP) | VAF 59/234 reads (25%) | catalogued as COSV100363536; called by muse, mutect2, varscan2
- TTC39A | c.1590C>T p.S530= (on ENST00000447632 / NM_001297665.1; = p.S495= on NM_001080494.3) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99396486; called by muse, mutect2, varscan2
- TTN | c.17880C>T p.G5960= (on ENST00000591111; = p.G5033= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs771457393, COSV100600653; called by muse, mutect2, varscan2
- ZNF75A | c.645A>G p.K215= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV101556621; called by muse, mutect2, varscan2
